Surgical pathology report (de-identified scan), TCGA case TCGA-32-1987, project TCGA-GBM (Glioblastoma Multiforme), tissue source site St. Joseph's Hospital (AZ), specimen TCGA-32-1987-01A (Primary Tumor).

NEUROPATHOLOGY REPORT

SPECIMEN SOURCE:

1. Brain tumor
2. Brain tumor

GBM [REDACTED]
CONTROL [REDACTED]

CLINICAL DIAGNOSIS:

Brain tumor

TCGA-32-1987

GROSS DESCRIPTION:

1. Received fresh for frozen section are three portions of tan soft tissue aggregating to 0.9 x 0.5 x 0.3 cm. A smear preparation is performed. Entirely frozen on one chuck.

FROZEN SECTION DIAGNOSIS:

GLIOBLASTOMA. [REDACTED]

2. Received in formalin are multiple portions of tan-pink to brown soft

GROSS DESCRIPTION:

tissue aggregating to 1.6 x 1.6 x 1.2 cm. The largest portion is serially sectioned. The specimen is entirely submitted as:

- A-B) Serial sections of largest portion of tissue
- C) Remaining fragments of tissue

MICROSCOPIC DESCRIPTION:

1, 2. Sections demonstrate a markedly hypercellular glial neoplasm. It is composed of moderately atypical spindle-shaped fibrillary astrocytes. These tend to be arranged in well-defined fascicles. Whereas the tumor demonstrates an infiltrative interface with the parenchyma, this invasion is somewhat limited. Angiocentric spread is focally prominent. Numerous mitotic figures are seen. Microvascular proliferation is noted and there are large areas of tumor necrosis. In some areas, the stroma is somewhat myxoid. Features strongly suggesting a sarcomatous phenotype are not seen. However, the growth pattern is suggestive enough to warrant further analysis.

DIAGNOSIS:

(PROVISIONAL):

- 1, 2. BRAIN TUMOR, BIOPSY AND RESECTION:

CONSISTENT WITH GLIOBLASTOMA, PENDING ADDITIONAL STUDIES. SEE DESCRIPTION.

ADDENDUM NEUROPATHOLOGY REPORT

ADDENDUM DISCUSSION:

The neoplastic cells are diffusely immunoreactive for GFAP. Trichrome stain does demonstrate focally prominent collagen production. However, this appears to be a desmoplastic response not associated with specific tumor cells. Even in these regions, the neoplastic cells are consistently GFAP positive.

ADDENDUM DIAGNOSIS:

- 1, 2. BRAIN TUMOR, BIOPSY AND RESECTION:

GLIOBLASTOMA (WHO GRADE IV).

Source: NCI Genomic Data Commons file 13bbca48-9009-4f35-8c0c-0e11fe00a727 (TCGA-32-1987.54EFD9DF-284F-44A9-A48D-192BFA3A5941.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).